Somatic mutation profile of tumor specimen TCGA-AG-A020-01A (aliquot TCGA-AG-A020-01A-21W-A096-10) from TCGA case TCGA-AG-A020, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 57.1 years (20,851 days).
Specimen TCGA-AG-A020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf1b907d-94ba-4dae-b45d-658e12b9330e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A020-11A (Solid Tissue Normal), aliquot TCGA-AG-A020-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2830e58-247d-4492-aa44-7a9bb59ab84d

The open-access MAF lists 91 somatic variants for this specimen: 69 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 21, Nonsense Mutation 8, Frame Shift Ins 2, RNA 1, In Frame Del 1, Nonstop Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3734dup p.A1246Gfs*10 | Frame Shift Ins (INS) | VAF 35/88 reads (40%) | catalogued as rs1114167595; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 104/272 reads (38%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.1147T>G p.W383G | Missense Mutation (SNP) | VAF 162/427 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62690170, COSV62701352, COSV62704397; called by muse, mutect2, varscan2
- GRXCR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 32/270 reads (12%) | catalogued as rs761349153, CM153971, COSV67670021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 133/317 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1610A>G p.D537G | Missense Mutation (SNP) | VAF 78/124 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555687605, COSV61684111, COSV61685387, COSV61697211; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 116/134 reads (87%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM10 | c.2078C>T p.A693V | Missense Mutation (SNP) | VAF 22/664 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV99545881; called by muse, mutect2
- ADAMTS18 | c.3620A>C p.K1207T | Missense Mutation (SNP) | VAF 36/496 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV99271993; called by muse, mutect2
- ALS2 | c.1793C>A p.T598K | Missense Mutation (SNP) | VAF 106/300 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as COSV99969104; called by muse, varscan2
- C3orf38 | c.632_633insG p.L213Sfs*39 | Frame Shift Ins (INS) | VAF 71/201 reads (35%) | catalogued as COSV100007373; called by mutect2, pindel, varscan2
- CACNA2D3 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 150/342 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as rs768809129, COSV55526000, COSV99872251; called by muse, mutect2, varscan2
- CHRNB3 | c.874G>A p.V292I | Missense Mutation (SNP) | VAF 108/574 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1455832559, COSV51496178; called by muse, mutect2, varscan2
- CNNM3 | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 139/337 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1360606313, COSV59709492; called by muse, mutect2, varscan2
- CSF1 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs548942397, COSV100294426; called by muse, mutect2, varscan2
- CSMD1 | c.2122C>T p.R708* (on ENST00000520002; = p.R707* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 35/128 reads (27%) | catalogued as COSV59352312; called by muse, mutect2, varscan2
- CYP7B1 | c.820T>A p.Y274N | Missense Mutation (SNP) | VAF 146/443 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100041303; called by muse, mutect2, varscan2
- CYP7B1 | c.819A>T p.K273N | Missense Mutation (SNP) | VAF 146/445 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100041304; called by muse, mutect2, varscan2
- DMD | c.1376A>C p.E459A | Missense Mutation (SNP) | VAF 46/1446 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as CD103867, COSV55868921, COSV55904712; called by muse, mutect2
- DNAH8 | c.12781G>T p.E4261* | Nonsense Mutation (SNP) | VAF 82/216 reads (38%) | catalogued as rs1444174890, COSV100544328, COSV59470807; called by muse, mutect2, varscan2
- DOCK2 | c.3493C>A p.P1165T | Missense Mutation (SNP) | VAF 74/176 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV99911465; called by muse, mutect2
- DUSP10 | c.1354A>T p.M452L | Missense Mutation (SNP) | VAF 188/433 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as COSV60458693; called by muse, mutect2, varscan2
- ERICH1 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100032326; called by muse, mutect2
- FLG | c.3465C>A p.H1155Q | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1238072637, COSV100911414; called by muse, mutect2
- FLNA | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV61043136; called by muse, mutect2, varscan2
- GRIA3 | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 117/298 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99989658; called by muse, mutect2, varscan2
- GTF3C1 | c.583C>T p.R195* | Nonsense Mutation (SNP) | VAF 31/77 reads (40%) | catalogued as COSV100649247; called by muse, mutect2, varscan2
- GTPBP1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 60/82 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755303735, COSV53286233; called by muse, mutect2, varscan2
- GUCY2F | c.3221C>A p.P1074Q | Missense Mutation (SNP) | VAF 207/483 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99484796; called by muse, mutect2, varscan2
- HAND1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 95/166 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1313460396, COSV50562859; called by muse, mutect2, varscan2
- HECW1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs777261023, COSV67826494; called by muse, mutect2, varscan2
- HUWE1 | c.11888G>A p.R3963H | Missense Mutation (SNP) | VAF 38/433 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53340160; called by muse, mutect2
- ITGAX | c.2159C>T p.P720L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs200637041, COSV99191587, COSV99192000; called by muse, mutect2, varscan2
- KCNC2 | c.1324G>T p.D442Y | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100128576; called by muse, mutect2, varscan2
- L3HYPDH | c.939G>A p.R313= | Splice Region (SNP) | VAF 62/150 reads (41%) | catalogued as COSV55967412; called by muse, mutect2, varscan2
- LILRB5 | c.1487G>A p.R496H (on ENST00000449561 / NM_001081442.3; = p.R495H on NM_006840.5) | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs367690586; called by muse, mutect2, varscan2
- LPA | c.2684G>T p.W895L | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV60305220; called by muse, mutect2, varscan2
- LRWD1 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371342787; called by muse, mutect2, varscan2
- MARK1 | c.1058T>A p.L353* | Nonsense Mutation (SNP) | VAF 63/172 reads (37%) | catalogued as COSV100857157; called by muse, mutect2, varscan2
- MYO3A | c.4162A>G p.R1388G | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV99779179; called by muse, mutect2
- OR10W1 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 123/235 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs200070425, COSV67720621; called by muse, mutect2, varscan2
- OR2L8 | c.729C>A p.H243Q | Missense Mutation (SNP) | VAF 101/290 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61727449; called by muse, mutect2
- P2RY2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 214/302 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1441881669, COSV60776944; called by muse, mutect2, varscan2
- PCCA | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 224/507 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747943045, COSV66187867; called by muse, mutect2, varscan2
- PCDH19 | c.259A>T p.I87F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99719485; called by muse, mutect2, varscan2
- PEG10 | c.524G>A p.R175H (on ENST00000482108 / NM_001040152.2; = p.R209H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV71788246, COSV71788437; called by muse, mutect2, varscan2
- PIK3CA | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.077); catalogued as COSV55951694; called by muse, mutect2, varscan2
- PLCG2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV63873773; called by muse, mutect2, varscan2
- PWWP3B | c.1729A>C p.T577P | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as COSV100531114, COSV100531609; called by muse, mutect2, varscan2
- RTN1 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 274/751 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as COSV50756561, COSV99955278; called by muse, mutect2, varscan2
- SAMD9 | c.2795C>G p.T932S | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV101180185; called by muse, mutect2, varscan2
- SMOC2 | c.730G>A p.G244S (on ENST00000356284 / NM_001166412.2; = p.G255S on NM_022138.3) | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs561879643, COSV62440555; called by muse, mutect2, varscan2
- SPTA1 | c.2945T>A p.V982D | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100934698; called by muse, mutect2, varscan2
- SZT2 | c.9730C>T p.P3244S (on ENST00000634258 / NM_001365999.1; = p.P3187S on NM_015284.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV100981256; called by muse, mutect2, varscan2
- TAS2R19 | c.352T>G p.S118A | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV101114595; called by muse, mutect2
- TENM1 | c.4820T>C p.V1607A | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV100949680; called by muse, mutect2, varscan2
- TENM2 | c.6130G>A p.E2044K (on ENST00000518659 / NM_001122679.2; = p.E1805K on NM_001080428.3) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69122861; called by muse, mutect2, varscan2
- TET1 | c.2052A>C p.K684N | Missense Mutation (SNP) | VAF 251/338 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV65390319; called by muse, mutect2, varscan2
- TMEM132D | c.1680T>G p.D560E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs968656736, COSV67158745; called by muse, mutect2, varscan2
- TRAF3IP2 | c.1596G>T p.W532C | Missense Mutation (SNP) | VAF 144/440 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60676392; called by muse, mutect2, varscan2
- TTN | c.33675A>T p.K11225N (on ENST00000591111; = p.K10298N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/542 reads (3%) | PolyPhen benign (0.22); catalogued as COSV100604858; called by muse, mutect2
- TTN | c.12821T>C p.V4274A (on ENST00000591111; = p.V4228A on NM_003319.4) | Missense Mutation (SNP) | VAF 124/321 reads (39%) | catalogued as COSV60179642; called by muse, mutect2, varscan2
- ULK1 | c.3151T>G p.*1051Gext*36 | Nonstop Mutation (SNP) | VAF 14/48 reads (29%) | catalogued as COSV58858326; called by muse, mutect2, varscan2
- ZBTB24 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 190/434 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1234245920, COSV57781154; called by muse, mutect2, varscan2
- ZIM3 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54144359; called by muse, mutect2, varscan2
- ZNF638 | c.2293G>T p.E765* | Nonsense Mutation (SNP) | VAF 45/120 reads (38%) | catalogued as COSV100038451; called by muse, mutect2, varscan2
- ZSWIM8 | c.3043G>T p.E1015* (on ENST00000605216 / NM_001242487.2; = p.E1020* on NM_015037.3) | Nonsense Mutation (SNP) | VAF 41/213 reads (19%) | catalogued as COSV67133418; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.196T>C p.W66R | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAAF1 | c.312_314del p.G105del | In Frame Del (DEL) | VAF 96/148 reads (65%) | called by pindel, varscan2
- BRDT | c.1107C>T p.F369= | Silent (SNP) | VAF 79/220 reads (36%) | catalogued as rs1249465244, COSV62863255; called by muse, mutect2, varscan2
- CACNA2D3 | c.729C>T p.N243= | Silent (SNP) | VAF 83/239 reads (35%) | catalogued as COSV55557591; called by muse, mutect2, varscan2
- DPP10 | c.748A>C p.R250= | Silent (SNP) | VAF 171/446 reads (38%) | catalogued as COSV59701675; called by muse, mutect2, varscan2
- FAM47C | c.2457C>T p.T819= | Silent (SNP) | VAF 33/103 reads (32%) | catalogued as rs782603504, COSV100792445, COSV63728098; called by muse, mutect2, varscan2
- FRYL | c.3147G>A p.A1049= | Silent (SNP) | VAF 216/521 reads (41%) | catalogued as rs1446687722, COSV51953042; called by muse, mutect2, varscan2
- FZD3 | c.813A>G p.Q271= | Silent (SNP) | VAF 87/226 reads (38%) | catalogued as rs769967376, COSV53536575; called by muse, mutect2, varscan2
- KIAA1958 | c.2103G>A p.S701= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as rs552377099, COSV61722734; called by muse, mutect2, varscan2
- KYNU | c.891G>A p.T297= | Silent (SNP) | VAF 141/373 reads (38%) | catalogued as rs140758594; called by muse, mutect2, varscan2
- MAMLD1 | c.1050G>A p.P350= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs782680929, COSV53377855; called by muse, mutect2, varscan2
- OPN1LW | c.714C>T p.C238= | Silent (SNP) | VAF 216/577 reads (37%) | catalogued as COSV64049465; called by muse, mutect2, varscan2
- OR2L13 | c.459C>A p.I153= | Silent (SNP) | VAF 30/536 reads (6%) | catalogued as COSV63556633; called by muse, mutect2
- OR4Q3 | c.174A>G p.Q58= | Silent (SNP) | VAF 183/419 reads (44%) | catalogued as COSV59178194, COSV59179416; called by muse, mutect2, varscan2
- PAPPA | c.2841T>C p.C947= | Silent (SNP) | VAF 83/283 reads (29%) | catalogued as COSV60285066; called by muse, mutect2, varscan2
- RIMS2 | c.1269T>G p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 83/217 reads (38%) | catalogued as COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- SEL1L | c.990G>A p.S330= | Silent (SNP) | VAF 50/165 reads (30%) | catalogued as rs754518891, COSV60921349; called by muse, mutect2, varscan2
- SFMBT2 | c.1257C>A p.P419= | Silent (SNP) | VAF 46/716 reads (6%) | catalogued as COSV100738782; called by muse, mutect2
- SLITRK2 | c.54G>A p.Q18= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV59426998, COSV59428388; called by muse, mutect2, varscan2
- SRPX | c.780A>G p.K260= | Silent (SNP) | VAF 110/243 reads (45%) | catalogued as COSV59439873; called by muse, mutect2, varscan2
- SYPL1 | c.444A>G p.K148= | Silent (SNP) | VAF 55/135 reads (41%) | catalogued as COSV99163435; called by muse, mutect2, varscan2
- TBX21 | c.1503C>T p.R501= | Silent (SNP) | VAF 41/86 reads (48%) | catalogued as rs1289687933, COSV51597122; called by muse, mutect2, varscan2
- UNC79 | c.4080C>G p.L1360= (on ENST00000393151 / NM_001346218.2; = p.L1183= on NM_020818.5) | Silent (SNP) | VAF 146/407 reads (36%) | catalogued as COSV56375384, COSV56397341; called by muse, mutect2, varscan2
- SSPOP | n.9100G>A | RNA (SNP) | VAF 4/33 reads (12%) | catalogued as rs1406971886, COSV65128676; called by muse, varscan2
